Somatic mutation profile of tumor specimen TARGET-40-PANMIG-01A (aliquot TARGET-40-PANMIG-01A-01Y) from TARGET case TARGET-40-PANMIG, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.7 years (5,360 days).
Specimen TARGET-40-PANMIG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b021f55-bdf4-4fdf-925b-d3eab518eeaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANMIG-10A (Blood Derived Normal), aliquot TARGET-40-PANMIG-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd1c2d4d-7e47-4401-b227-b18a8e212fe4

The open-access MAF lists 31 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Intron 4, Splice Site 2, 3'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1696-1G>A p.X566_splice | Splice Site (SNP) | VAF 21/29 reads (72%) | catalogued as rs794727199, CS951523, COSV57329272; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRX | c.5787-2A>G p.X1929_splice | Splice Site (SNP) | VAF 71/79 reads (90%) | catalogued as COSV100970140; called by muse, mutect2, varscan2
- MICAL3 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99260946; called by muse, varscan2
- PCDHB12 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs1297969778, COSV53395290; called by muse, mutect2
- PNPLA6 | c.2437A>T p.T813S (on ENST00000414982 / NM_001166111.2; = p.T765S on NM_006702.5) | Missense Mutation (SNP) | VAF 97/542 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs772492685; called by muse, mutect2, varscan2
- SI | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV52274668; called by muse, mutect2, varscan2
- ZNF157 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs760600482, COSV65659233; called by muse, mutect2, varscan2
- ZNF730 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101659640; called by muse, mutect2, varscan2
- ADAMTS6 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- AKR1D1 | c.61A>T p.I21F | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CHSY3 | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CNTNAP5 | c.1074T>A p.F358L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IGHV3-43 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); called by muse, mutect2
- IGSF21 | c.1256T>A p.L419Q | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPRID1 | c.3114G>T p.K1038N | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LAMA2 | c.8622A>T p.K2874N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MYH4 | c.4798T>C p.S1600P | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- OR2H1 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2
- OR2T1 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PDE4B | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 64/519 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- INHBB | c.894C>T p.G298= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV54678760; called by muse, mutect2
- JAKMIP1 | c.759C>T p.A253= | Silent (SNP) | VAF 61/196 reads (31%) | catalogued as rs369824626; called by muse, mutect2, varscan2
- MICAL3 | c.621G>A p.K207= | Silent (SNP) | VAF 85/380 reads (22%) | called by muse, varscan2
- TDRD12 | c.1836A>C p.A612= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- ARMC8 | c.1218-20A>T | Intron (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- MDC1 | c.3013+51_3013+54del | Intron (DEL) | VAF 165/382 reads (43%) | catalogued as rs1244877370; called by mutect2, pindel, varscan2
- MIR99A | n.57G>A | RNA (SNP) | VAF 14/40 reads (35%) | catalogued as rs913397001; called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53424A>C | Intron (SNP) | VAF 83/178 reads (47%) | called by muse, mutect2, varscan2
- PMS2P1 | chr7:100336053 A>G | 5'Flank (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- RPL9 | c.259-11A>T | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ZBTB24 | c.*134A>G | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2
